National Lung Screening Trial (NLST) participant 109521 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 63 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer.
- T1: No screening result: Not Compliant - Refused a screen.
- T2: No screening result: Not Compliant - Refused a screen.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T3; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,310, study year T3. Site: lung, NOS (ICD-O-3 C34.9), determined from cytology. Primary tumour location: unknown location. Histology: small cell carcinoma, NOS (ICD-O-3 8041/3). AJCC 6th edition staging: stage IIIB (best stage, from clinical TNM); clinical T4 N2 M0 (stage IIIB). AJCC 7th edition staging: stage IV; clinical T4 N2 M1a. Summary stage: regional. VALCSG stage (the small-cell staging system; ACRIN recorded it for all its lung cancers): extensive.

Follow-up
Last known free of lung cancer: day 1,148.
